MMRF case MMRF_1308 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/fa1557d6-e713-4e32-804b-3e9f8751a282

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.3 years (19,463 days); ISS stage: I; Days to last known disease status: 1,524 days (4.2 years); Days to last follow up: 1,524 days (4.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 232 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 138 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 26 days; Days to treatment end: 102 days.
   Treatment given: Therapeutic agents: Dexamethasone + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 283 days; Days to treatment end: 563 days (1.5 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 354 days; Days to treatment end: 563 days (1.5 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide + Panobinostat; Regimen or line of therapy: Third line of therapy; Days to treatment start: 563 days (1.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -10 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 166 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 8.85 g/L; Immunoglobulin A 1.26 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 1.91 µg/mL; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.53 mmol/L; Albumin 45 g/L; Total Protein 7.2 g/dL; Glucose 5.17 mmol/L.
- Day 102 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.37 mg/dL; Immunoglobulin G 0.79 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.52 g/L; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.89 mmol/L.
- Day 172 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.07 mg/dL; Immunoglobulin G 5.85 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 44 g/L; Total Protein 6.2 g/dL; Glucose 4.95 mmol/L.
- Day 271 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 41.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.31 mg/dL; Immunoglobulin G 7.98 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 1.44 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 6.7 g/dL; Glucose 4.62 mmol/L.
- Day 354 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 54.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.18 mg/dL; Immunoglobulin G 8.23 g/L; Immunoglobulin A 1.31 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 1.79 ×10⁹/L; Platelets 312 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 4.79 mmol/L.
- Day 460 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 35.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.83 mg/dL; Immunoglobulin G 6.54 g/L; Immunoglobulin A 1.12 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 308 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.45 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 6.16 mmol/L.
- Day 529 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 41.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.77 mg/dL; Immunoglobulin G 6.27 g/L; Immunoglobulin A 1.14 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 335 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.43 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 4.73 mmol/L.
- Day 621 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 29.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 5.96 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 34 g/L; Total Protein 6 g/dL; Glucose 4.79 mmol/L.
- Day 733 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 24.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 5.7 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 4.26 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 33 g/L; Total Protein 5.7 g/dL; Glucose 4.13 mmol/L.
- Day 818 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 25.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.52 mg/dL; Immunoglobulin G 5.94 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 5.6 g/dL; Glucose 4.46 mmol/L.
- Day 901 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 22.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.68 mg/dL; Immunoglobulin G 6.12 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 33 g/L; Total Protein 5.3 g/dL; Glucose 4.62 mmol/L.
- Day 971 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 22.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 5.5 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.28 mmol/L; Albumin 34 g/L; Total Protein 5.5 g/dL; Glucose 4.29 mmol/L.
- Day 1,055: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 9.65 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 1.83 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.03 mmol/L; Albumin 31 g/L; Total Protein 5.4 g/dL; Glucose 4.79 mmol/L.
- Day 1,139: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.53 mg/dL; Immunoglobulin G 7.78 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 1.95 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.43 mmol/L; Albumin 35 g/L; Total Protein 6 g/dL; Glucose 5.12 mmol/L.
- Day 1,230 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.42 mg/dL; Immunoglobulin G 10 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 4.9 mmol/L.
- Day 1,314: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 22.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.58 mg/dL; Immunoglobulin G 9.18 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 32 g/L; Total Protein 5.1 g/dL; Glucose 5.12 mmol/L.
- Day 1,432 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 0.99 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 5.9 g/dL; Glucose 4.4 mmol/L.
- Day 1,524 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 1.06 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 1.34 µg/mL; Lactate Dehydrogenase 1.88 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Total Protein 6.3 g/dL; Glucose 4.07 mmol/L.

Other clinical attributes
- Day -10: Weight: 103 kg; Height: 191 cm.

Biospecimens (3 samples)
- Sample MMRF_1308_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -10 days.
- Sample MMRF_1308_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -10 days.
- Sample MMRF_1308_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 271 days.
